Somatic mutation profile of tumor specimen TCGA-G3-A3CJ-01A (aliquot TCGA-G3-A3CJ-01A-11D-A20W-10) from TCGA case TCGA-G3-A3CJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.9 years (19,305 days).
Specimen TCGA-G3-A3CJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff00aba9-0966-4cc8-b3dd-829facee8d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A3CJ-10A (Blood Derived Normal), aliquot TCGA-G3-A3CJ-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87ea73bf-710c-4768-bc3f-5d77c68b6ee8

The open-access MAF lists 385 somatic variants for this specimen: 363 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 322, Missense Mutation 26, Silent 12, Splice Site 11, RNA 4, Intron 4, Nonsense Mutation 3, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by mutect2, varscan2
- AGL | c.3949+1del | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | catalogued as COSV99648318; called by mutect2, pindel
- ALB | c.1289+1G>A p.X430_splice | Splice Site (SNP) | VAF 42/106 reads (40%) | catalogued as rs779988470, CS122001, COSV55735420, COSV55742076; called by mutect2, varscan2
- ALPK2 | c.4928del p.P1643Qfs*20 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | catalogued as rs1345298461, COSV64491662; called by mutect2, pindel
- ANKS1A | c.959del p.P320Hfs*25 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as COSV64461548; called by mutect2, pindel, varscan2
- ANO8 | c.413del p.G138Afs*80 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | catalogued as COSV99344329; called by mutect2, pindel
- ARHGAP6 | c.1348del p.R450Vfs*20 | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | catalogued as COSV57291137; called by mutect2, pindel
- ARID5B | c.3191del p.G1064Afs*43 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as COSV54429808, COSV99689130; called by mutect2, pindel
- ATP13A1 | c.2393del p.G798Afs*55 | Frame Shift Del (DEL) | VAF 6/69 reads (9%) | catalogued as rs1165294989; called by mutect2, pindel
- B3GALT1 | c.307del p.D103Mfs*10 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | catalogued as rs767927493, COSV100003016; called by mutect2, pindel
- C12orf40 | c.364del p.E122Kfs*24 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | catalogued as COSV61138068; called by mutect2, pindel
- CCDC88A | c.4147T>G p.F1383V | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV55055692; called by mutect2, varscan2
- CEMIP2 | c.1426A>G p.I476V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV65485343; called by mutect2, varscan2
- CETN1 | c.346del p.D116Mfs*11 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | catalogued as COSV59120783; called by mutect2, pindel
- CFP | c.1055del p.G352Afs*27 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as COSV99901588; called by mutect2, pindel
- CLIP3 | c.32del p.P11Rfs*86 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as COSV53078952; called by mutect2, pindel
- COL7A1 | c.7272G>A p.R2424= | Splice Region (SNP) | VAF 62/148 reads (42%) | catalogued as COSV60390604; called by mutect2, varscan2
- CTSF | c.952del p.L318Sfs*28 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as rs758605201; called by mutect2, pindel
- DYNC1I1 | c.354del p.P119Hfs*2 | Frame Shift Del (DEL) | VAF 10/122 reads (8%) | catalogued as COSV61460241; called by mutect2, pindel
- ELOA2 | c.710T>A p.L237* | Nonsense Mutation (SNP) | VAF 80/187 reads (43%) | catalogued as COSV55292676; called by mutect2, varscan2
- ERI1 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV51570469; called by muse, varscan2
- FYB2 | c.10del p.E4Kfs*3 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV58588440; called by mutect2, pindel
- GCN1 | c.5137C>A p.R1713S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56103004, COSV56110983; called by mutect2, varscan2
- GREM1 | c.104del p.P35Rfs*49 | Frame Shift Del (DEL) | VAF 10/113 reads (9%) | catalogued as COSV55715863; called by mutect2, pindel
- H1-2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs186228942, COSV59189531; called by mutect2, varscan2
- H4C7 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1019581035, COSV55099056; called by mutect2, varscan2
- HERC4 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53268064; called by mutect2, varscan2
- HIF3A | c.1552G>A p.A518T (on ENST00000377670 / NM_152795.4; = p.A449T on NM_022462.4) | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs562383855, COSV52195459, COSV52202640; called by mutect2, varscan2
- IMMT | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54485169; called by mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs1561359523; called by mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KHDRBS2 | c.674del p.G225Efs*4 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV55468978; called by pindel, varscan2
- KMT2B | c.2314del p.L772Wfs*17 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | catalogued as COSV52890708; called by mutect2, pindel
- KREMEN1 | c.230del p.G77Afs*15 (on ENST00000407188; = p.G79Afs*15 on NM_032045.5) | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | catalogued as rs775709729; called by mutect2, pindel
- LAMA2 | c.3787G>T p.E1263* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV70337146, COSV70352184; called by mutect2, varscan2
- MAB21L4 | c.1328del p.G443Efs*90 (on ENST00000388934 / NM_001085437.3; = p.G275Efs*90 on NM_024861.4) | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | catalogued as COSV56743402; called by mutect2, pindel
- MAP11 | c.401del p.G134Efs*38 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as rs1201713096; called by mutect2, pindel
- MAPKAPK5 | c.1394A>T p.E465V (on ENST00000551404 / NM_139078.3; = p.E463V on NM_003668.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV73436035; called by mutect2, varscan2
- MEPE | c.122del p.N41Tfs*14 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs768254676; called by pindel, varscan2
- MGA | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV54947814; called by muse, mutect2, varscan2
- MIGA1 | c.1549del p.R517Dfs*4 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as COSV100889751; called by mutect2, pindel
- MIP | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 103/286 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV57787967; called by mutect2, varscan2
- MSH3 | c.20del p.A7Gfs*18 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | catalogued as COSV54153814; called by mutect2, pindel
- NAIF1 | c.278del p.G93Vfs*28 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV100895692; called by mutect2, pindel
- NCK2 | c.1132del p.A378Pfs*72 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | catalogued as COSV51896653; called by mutect2, pindel
- NRIP1 | c.748del p.R250Gfs*17 | Frame Shift Del (DEL) | VAF 12/138 reads (9%) | catalogued as COSV100012815; called by mutect2, pindel
- NUP98 | c.3983del p.N1328Tfs*89 (on ENST00000359171 / NM_001365126.1; = p.N1311Tfs*89 on NM_016320.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | catalogued as rs1214420150; called by mutect2, varscan2
- OR2T34 | c.801del p.S268Vfs*10 | Frame Shift Del (DEL) | VAF 18/174 reads (10%) | catalogued as COSV100170337; called by mutect2, pindel
- OR52B6 | c.562del p.C188Afs*41 | Frame Shift Del (DEL) | VAF 10/126 reads (8%) | catalogued as COSV61448513; called by mutect2, pindel
- OR52L1 | c.20del p.F7Sfs*8 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as COSV100176389; called by pindel, varscan2
- OR5B3 | c.660del p.F220Lfs*5 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | catalogued as COSV58676958; called by mutect2, pindel
- PCDHGA2 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as rs750116599, COSV53892669; called by mutect2, varscan2
- PKP4 | c.1718A>G p.K573R | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs750922618, COSV67675253; called by mutect2, varscan2
- PLEKHG3 | c.2336del p.G779Afs*50 (on ENST00000394691; = p.G835Afs*50 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | catalogued as COSV55980958; called by mutect2, pindel
- POLD1 | c.3067+1del | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | catalogued as COSV54531077; called by mutect2, pindel
- POLR2B | c.2078A>G p.Y693C | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58898167, COSV58901533; called by mutect2, varscan2
- PPP1R1A | c.344del p.P115Hfs*92 | Frame Shift Del (DEL) | VAF 6/80 reads (8%) | catalogued as COSV54492303; called by mutect2, pindel
- PRICKLE1 | c.1580T>C p.L527P | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV58203470, COSV58209726; called by mutect2, varscan2
- PRR16 | c.830del p.P277Lfs*20 (on ENST00000407149 / NM_001300783.2; = p.P254Lfs*20 on NM_016644.2) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as COSV65401020; called by mutect2, pindel
- RABGAP1 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV65391621; called by muse, mutect2, varscan2
- RAD54B | c.2248-2A>G p.X750_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | catalogued as COSV60249292; called by muse, varscan2
- RELCH | c.1298del p.N433Tfs*73 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | catalogued as COSV56884160, COSV56884850; called by mutect2, pindel
- SLC2A8 | c.708del p.I237Sfs*27 | Frame Shift Del (DEL) | VAF 8/87 reads (9%) | catalogued as rs199808560; called by mutect2, pindel
- SPTAN1 | c.1351del p.A451Rfs*33 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | catalogued as COSV100824119; called by mutect2, pindel
- SPTBN1 | c.4969del p.A1657Pfs*27 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | catalogued as COSV61695341; called by mutect2, pindel
- SRMS | c.126del p.T43Rfs*28 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | catalogued as rs1411114270; called by mutect2, pindel
- SSBP4 | c.774del p.G259Afs*35 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV99526044; called by mutect2, pindel
- STAR | c.129del p.T44Pfs*65 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | catalogued as COSV99379203; called by mutect2, pindel
- STOX2 | c.795del p.K265Nfs*4 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as rs1456318764, COSV57849231; called by mutect2, pindel
- STOX2 | c.920del p.P307Lfs*4 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | catalogued as COSV57853295; called by mutect2, pindel
- SUPT5H | c.64del p.E22Rfs*5 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as COSV100782074, COSV63240827; called by mutect2, pindel
- TALDO1 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV59796726; called by mutect2, varscan2
- TBX21 | c.766del p.Q256Rfs*2 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | catalogued as COSV51595049; called by mutect2, pindel
- THSD7B | c.4078A>G p.I1360V (on ENST00000272643; = p.I1358V on NM_001316349.2) | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770334613, COSV55649409; called by mutect2, varscan2
- TMEM237 | c.205A>T p.T69S (on ENST00000409883 / NM_001044385.3; = p.T61S on NM_152388.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs376226585; called by muse, mutect2, varscan2
- TTLL8 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs536172014, COSV56721952; called by muse, varscan2
- TTN | c.31809del p.V10604Ffs*2 (on ENST00000591111; = p.V9677Ffs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as COSV59925588; called by mutect2, pindel
- UGGT2 | c.1976del p.L659Wfs*4 | Frame Shift Del (DEL) | VAF 12/140 reads (9%) | catalogued as rs762239651; called by mutect2, pindel
- UHRF1BP1L | c.3985del p.R1329Gfs*12 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as COSV54436356; called by mutect2, pindel
- WDR18 | c.556del p.L186Wfs*13 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs1235500487; called by mutect2, pindel
- WDR74 | c.661del p.L221* | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | catalogued as COSV53679316; called by mutect2, pindel
- WNK4 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53819809; called by muse, varscan2
- ZNF14 | c.4del p.D2Tfs*10 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV59848520; called by mutect2, pindel
- ZNF205 | c.829del p.R277Afs*48 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | catalogued as COSV54622692; called by mutect2, pindel
- ZNF429 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV61914288; called by muse, mutect2, varscan2
- ZNF518A | c.57del p.D20Ifs*4 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as COSV60151560; called by pindel, varscan2
- ZNF583 | c.254del p.N85Tfs*18 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | catalogued as COSV52402755; called by mutect2, pindel
- ZRANB3 | c.1965A>G p.I655M | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV51492190; called by muse, mutect2, varscan2
- ABCA1 | c.4044del p.F1348Lfs*19 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- ABCG8 | c.145del p.V49Sfs*43 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- AC098582.1 | c.2229del p.L744Ffs*4 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel
- ACP2 | c.772+1del p.X258_splice | Splice Site (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ADAM8 | c.495del p.T166Pfs*65 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- ADCY2 | c.2593del p.A865Lfs*9 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- AFG1L | c.1118del p.L373Yfs*19 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- AKAP6 | c.5984del p.N1995Tfs*8 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- ANKRD16 | c.920del p.N307Ifs*25 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by pindel, varscan2
- ANO8 | c.2097del p.G700Afs*39 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ANO9 | c.1759del p.L587Wfs*51 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- AP3S2 | c.460del p.L154Ffs*12 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- APC | c.2274del p.A759Pfs*2 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- ARHGAP6 | c.80del p.F27Sfs*16 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ASNS | c.1118del p.G373Vfs*22 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by pindel, varscan2
- ASTN2 | c.2497del p.L833Ffs*34 (on ENST00000313400 / NM_001365069.1; = p.L782Ffs*34 on NM_014010.5) | Frame Shift Del (DEL) | VAF 10/122 reads (8%) | called by mutect2, pindel
- ASXL3 | c.6717del p.K2239Nfs*4 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- ATAD2B | c.2247del p.K749Nfs*43 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by pindel, varscan2
- ATP1A4 | c.136del p.E46Kfs*9 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- ATXN10 | c.218del p.N73Tfs*8 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- ATXN2L | c.2319del p.A774Lfs*28 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- BCL2L1 | c.93del p.E32Rfs*34 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- BCOR | c.948del p.S317Lfs*61 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- BRCC3 | c.213del p.I71Mfs*20 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- BRWD3 | c.4256del p.L1419Yfs*34 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- BTBD6 | c.742del p.V248Sfs*6 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- BTBD7 | c.2535del p.T846Pfs*22 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- C12orf50 | c.619del p.V207Sfs*12 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- C1QA | c.170del p.P57Lfs*225 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- C1orf131 | c.415del p.R139Efs*3 | Frame Shift Del (DEL) | VAF 7/80 reads (9%) | called by mutect2, pindel
- CALCOCO1 | c.278del p.P93Qfs*11 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- CAMSAP1 | c.3788del p.G1263Afs*30 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- CAPN15 | c.1623del p.S542Qfs*14 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- CARMIL2 | c.1259del p.L420Pfs*92 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- CBR4 | c.239del p.L80Wfs*2 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- CCDC70 | c.209del p.G70Afs*85 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- CDON | c.2415del p.R806Gfs*22 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- CEBPG | c.258del p.A87Hfs*25 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CEP170B | c.3013del p.R1005Vfs*28 (on ENST00000453495; = p.R934Vfs*28 on NM_015005.3) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CFAP46 | c.687del p.Q230Sfs*2 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- CGNL1 | c.2608del p.E870Rfs*7 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CHD2 | c.2014del p.E672Kfs*22 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- CHERP | c.2446del p.R816Gfs*35 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- CLCNKB | c.1741del p.L581Wfs*13 | Frame Shift Del (DEL) | VAF 10/125 reads (8%) | called by mutect2, pindel
- CMTR2 | c.1574del p.K525Sfs*3 | Frame Shift Del (DEL) | VAF 8/93 reads (9%) | called by mutect2, pindel
- CNTN5 | c.413del p.N138Mfs*5 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- CNTRL | c.1106del p.N369Ifs*59 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- COG6 | c.247del p.S83Vfs*2 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- COG8 | c.610del p.S204Pfs*4 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- COL27A1 | c.1758del p.T587Pfs*37 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- COL7A1 | c.3636del p.F1213Sfs*52 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- COL9A2 | c.645del p.D215Efs*103 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- COP1 | c.1611del p.V538* | Frame Shift Del (DEL) | VAF 8/95 reads (8%) | called by mutect2, pindel
- COX18 | c.598+1del p.X200_splice | Splice Site (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- CRAMP1 | c.2793del p.A932Qfs*26 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- CRY2 | c.887del p.K296Sfs*68 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel
- CSMD1 | c.9785del p.L3262* (on ENST00000520002; = p.L3261* on NM_033225.6) | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- CSNK1E | c.954del p.Q319Sfs*58 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel
- CX3CL1 | c.512del p.P171Rfs*258 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- DDX53 | c.1431del p.K477Nfs*34 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- DENND2D | c.511del p.D171Mfs*49 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- DLC1 | c.1488del p.I496Mfs*8 (on ENST00000276297 / NM_001348081.2; = p.I59Mfs*8 on NM_006094.5) | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- DNAJA4 | c.838del p.T280Hfs*16 (on ENST00000343789; = p.T309Hfs*16 on NM_018602.3) | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- DNAJC10 | c.42_54del p.L14Ffs*5 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | called by pindel, varscan2
- DNAJC10 | c.977del p.N326Tfs*18 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- DNAJC22 | c.845del p.L282Wfs*19 | Frame Shift Del (DEL) | VAF 6/69 reads (9%) | called by mutect2, pindel
- DRP2 | c.1200del p.S401Qfs*7 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- ECM2 | c.22del p.C8Vfs*31 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- ECPAS | c.75del p.Q25Hfs*28 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- EDARADD | c.215del p.N72Ifs*41 (on ENST00000334232 / NM_145861.4; = p.N62Ifs*41 on NM_080738.4) | Frame Shift Del (DEL) | VAF 21/243 reads (9%) | called by mutect2, pindel
- EHD3 | c.45del p.E16Rfs*6 | Frame Shift Del (DEL) | VAF 9/102 reads (9%) | called by mutect2, pindel
- EHMT2 | c.2554del p.D852Tfs*39 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- EIF4G2 | c.574del p.L192Sfs*66 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- ELAVL3 | c.1092del p.Q364Hfs*56 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- ENTPD6 | c.1243+2del p.X415_splice | Splice Site (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ENTPD6 | c.1321del p.Q441Rfs*11 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- EPHA7 | c.145del p.S49Pfs*52 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- EPPK1 | c.4445del p.K1482Sfs*57 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- EPS8 | c.1707del p.V570Ffs*19 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- ERCC6L2 | c.4053del p.F1351Lfs*30 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by pindel, varscan2
- FAAH2 | c.1424del p.X475_splice | Splice Site (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- FAM83B | c.2294del p.P765Qfs*4 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel
- FAM90A1 | c.556del p.L186Sfs*6 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- FAT2 | c.10531del p.L3511Sfs*4 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- FBXO44 | c.622del p.E208Rfs*52 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FECH | c.728del p.K243Rfs*38 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- FIGNL2 | c.258del p.S87Pfs*49 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- FNIP2 | c.1779del p.W594Gfs*82 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- FRMPD4 | c.2190del p.I731Sfs*24 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- FUT7 | c.841del p.R281Efs*10 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- FYN | c.1305del p.E436Rfs*35 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | called by pindel, varscan2
- FYTTD1 | c.578del p.F193Sfs*5 | Frame Shift Del (DEL) | VAF 6/80 reads (8%) | called by mutect2, pindel
- FZD5 | c.1431del p.W478Gfs*129 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- GABBR1 | c.254del p.G85Afs*21 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- GAK | c.3490del p.V1164Sfs*41 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- GALT | c.1114del p.D372Tfs*28 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- GCAT | c.558del p.K187Sfs*66 | Frame Shift Del (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- GDA | c.1251del p.F417Lfs*15 | Frame Shift Del (DEL) | VAF 11/118 reads (9%) | called by pindel, varscan2
- GIGYF2 | c.2370+2del p.X790_splice | Splice Site (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- GLRA2 | c.672del p.E225Kfs*34 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- GNRHR | c.979del p.S327Lfs*4 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- GPRC5C | c.1078del p.D360Tfs*14 (on ENST00000652232; = p.D315Tfs*14 on NM_018653.4) | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel
- GPRIN1 | c.2164del p.S722Pfs*6 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- GRIN2A | c.14del p.G5Afs*30 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- GRK7 | c.*1del | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- GRM3 | c.1337del p.P446Qfs*8 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- GSE1 | c.2402del p.L801* | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- HEATR9 | c.15del p.K5Nfs*95 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- HEPH | c.380del p.P127Lfs*23 (on ENST00000343002; = p.P181Lfs*23 on NM_138737.5) | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- HERC4 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | called by mutect2, varscan2
- HEXA | c.218del p.F73Sfs*27 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- HEXIM1 | c.414del p.E139Rfs*32 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- HMCN1 | c.7697del p.N2566Mfs*11 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- HMG20A | c.42del p.F14Lfs*18 | Frame Shift Del (DEL) | VAF 8/87 reads (9%) | called by mutect2, pindel
- HNF4A | c.242del p.K81Rfs*45 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- HRG | c.188del p.N63Ifs*7 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- HS6ST3 | c.336del p.E113Rfs*19 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- HTATSF1 | c.1207del p.S403Qfs*9 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- HTR1B | c.747del p.K249Nfs*3 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- ILVBL | c.1494del p.G499Vfs*43 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ILVBL | c.565del p.L189* | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- IRF7 | c.509del p.P170Hfs*41 (on ENST00000397566; = p.P157Hfs*41 on NM_001572.5) | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | called by mutect2, pindel
- JMJD7-PLA2G4B | c.361del p.Q121Sfs*44 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- KCNK10 | c.557del p.L186Yfs*41 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by pindel, varscan2
- KIAA0586 | c.2601del p.K867Nfs*47 (on ENST00000619416 / NM_001244190.2; = p.K806Nfs*47 on NM_014749.5) | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- KIAA1210 | c.4951del p.S1651Qfs*81 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- KIAA2026 | c.320del p.G107Afs*57 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- KIF25 | c.1105del p.R369Efs*25 (on ENST00000354419 / NM_030615.2; = p.R317Efs*25 on NM_005355.3) | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel
- KLK13 | c.659del p.G220Afs*54 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- KLK4 | c.292del p.E98Rfs*71 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- KMT2A | c.10541del p.G3514Vfs*34 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | called by mutect2, pindel
- KMT2D | c.15195_15196del p.W5065Cfs*6 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- KTN1 | c.2205del p.K735Nfs*10 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- KXD1 | c.226del p.D76Tfs*12 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- LAMA5 | c.6768del p.T2257Pfs*33 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- LIPC | c.1147del p.M383Cfs*31 | Frame Shift Del (DEL) | VAF 17/228 reads (7%) | called by mutect2, pindel
- LIPC | c.1490del p.K497Rfs*6 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- LNPEP | c.1825del p.T609Pfs*10 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- LONP2 | c.664del p.I222Lfs*4 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | called by mutect2, pindel
- LRRC4B | c.1995del p.Y665* | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- LUC7L | c.825del p.R276Vfs*104 (on ENST00000293872 / NM_201412.3; = p.R276Vfs*63 on NM_018032.5) | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel
- MAGEB2 | c.178del p.Q60Rfs*52 | Frame Shift Del (DEL) | VAF 6/69 reads (9%) | called by mutect2, pindel
- MAK16 | c.354del p.Q118Hfs*3 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- MCM8 | c.114del p.D39Ifs*2 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- MED29 | c.478del p.T160Rfs*82 (on ENST00000615911; = p.T139Rfs*82 on NM_017592.4) | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- MICALL1 | c.848del p.K283Sfs*58 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- MID1 | c.722del p.L241Wfs*22 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- MLH1 | c.1078del p.V360Lfs*7 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- MLXIP | c.1614del p.F538Lfs*9 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- MOGS | c.1538del p.P513Qfs*7 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- MROH6 | c.292del p.Q98Rfs*67 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- MSH2 | c.1985del p.Q662Rfs*23 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- MSH6 | c.3969del p.F1323Lfs*4 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- MSN | c.234del p.F78Lfs*16 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- MTMR1 | c.1080del p.S360Rfs*28 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- MYD88 | c.321del p.S108Afs*11 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel
- MYO15A | c.9513del p.Q3172Rfs*27 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- MYO9B | c.3807del p.E1270Rfs*183 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel
- MYOM1 | c.16del p.Y6Ifs*21 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- MYT1 | c.856del p.E286Kfs*26 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- N4BP3 | c.807del p.K270Rfs*28 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- NCAPD3 | c.3867+1del p.X1289_splice | Splice Site (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- NECTIN3 | c.160+1del | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- NEFH | c.1562del p.K521Rfs*88 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- NFKB2 | c.1172del p.G391Afs*91 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- NFKBIL1 | c.441del p.W148Gfs*122 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- NLRC3 | c.179del p.D60Afs*12 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- NOC3L | c.1602del p.F534Lfs*5 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by mutect2, pindel
- NPR2 | c.660del p.N220Kfs*26 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- NRAP | c.1746del p.K582Nfs*30 (on ENST00000359988 / NM_001322945.2; = p.K547Nfs*30 on NM_006175.4) | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- NSD3 | c.2959A>T p.N987Y | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NTN5 | c.366del p.F123Sfs*26 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- NUBP1 | c.581del p.G194Efs*3 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- NWD1 | c.1683del p.A562Pfs*37 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- OR1J1 | c.923del p.S308* | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- OR2AE1 | c.454del p.A152Hfs*3 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- PBRM1 | c.2581del p.I861Yfs*6 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- PCGF2 | c.673del p.L225Sfs*14 | Frame Shift Del (DEL) | VAF 11/115 reads (10%) | called by mutect2, pindel
- PCIF1 | c.1174del p.V392Wfs*10 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PCNT | c.5458del p.L1820Cfs*23 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PCSK4 | c.706del p.I236Sfs*10 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- PDZRN3 | c.2547del p.T850Rfs*37 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PEX6 | c.2091del p.K698Rfs*16 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- PGC | c.686del p.G229Vfs*61 | Frame Shift Del (DEL) | VAF 13/141 reads (9%) | called by mutect2, pindel
- PGP | c.648del p.C217Vfs*52 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- PHF2 | c.761del p.G254Afs*87 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- PHKG2 | c.1160del p.P387Lfs*10 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- PHOX2B | c.606del p.N203Tfs*106 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- PHRF1 | c.2292del p.S765Qfs*196 (on ENST00000264555 / NM_001286581.2; = p.S764Qfs*196 on NM_020901.4) | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- PHYHD1 | c.823del p.E275Rfs*31 (on ENST00000372592 / NM_001100876.2; = p.R268Efs*8 on NM_174933.4) | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- PLA2G4D | c.446del p.N149Tfs*41 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel
- PLEKHG4 | c.3418del p.E1140Rfs*12 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- PLEKHH3 | c.515del p.G172Vfs*26 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PLXNC1 | c.4431del p.Y1478Tfs*5 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- POLE | c.5699del p.F1900Sfs*4 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- POLR3A | c.1167del p.L390* | Frame Shift Del (DEL) | VAF 7/77 reads (9%) | called by mutect2, pindel
- POM121L12 | c.207del p.R70Afs*51 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- PRMT6 | c.421del p.E141Rfs*3 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- PRRC2A | c.4914del p.F1638Lfs*9 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- PRSS35 | c.742del p.S248Pfs*35 | Frame Shift Del (DEL) | VAF 5/60 reads (8%) | called by mutect2, pindel
- PSD4 | c.2788del p.H930Tfs*85 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- PSME4 | c.3121del p.A1041Qfs*32 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- PTGDR | c.98del p.G33Afs*36 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PTGDS | c.274del p.R92Efs*68 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- PTGDS | c.436del p.A146Pfs*14 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- PWWP2B | c.233del p.M78Sfs*108 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- PXDNL | c.3549del p.K1183Nfs*2 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- RAB21 | c.159+1del | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- RALGAPA1 | c.395del p.F132Sfs*23 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- RAVER2 | c.1807del p.T603Pfs*45 (on ENST00000294428 / NM_001366165.1; = p.T590Pfs*45 on NM_018211.4) | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel
- RBM6 | c.1294del p.T432Lfs*29 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- RBPJ | c.1170del p.A391Lfs*36 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- ROR2 | c.2496del p.Y833Tfs*157 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- RP1L1 | c.1872del p.S625Lfs*58 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel
- RSF1 | c.3069del p.F1023Lfs*69 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- RTL9 | c.983del p.P328Qfs*23 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- RTN1 | c.1270del p.E424Rfs*9 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- RUSC2 | c.3631del p.A1211Pfs*19 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- S100PBP | c.453del p.F151Lfs*31 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- SEC23IP | c.1448del p.F483Sfs*5 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- SHISA2 | c.837del p.F280Sfs*14 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- SLC25A12 | c.741del p.V248Sfs*19 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- SLC38A10 | c.941del p.G314Afs*51 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- SLC4A1AP | c.1549del p.S517Lfs*4 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- SLCO5A1 | c.1622+1del p.X541_splice | Splice Site (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- SMAD7 | c.9del p.T4Pfs*89 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel
- SMG6 | c.400del p.I134Lfs*39 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- SP6 | c.273del p.S93Pfs*47 | Frame Shift Del (DEL) | VAF 7/82 reads (9%) | called by mutect2, pindel
- SPATA22 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- SRGAP3 | c.1024del p.V342Sfs*30 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- SRPX | c.177del p.I60Sfs*3 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- SRRM2 | c.1181del p.P394Hfs*314 | Frame Shift Del (DEL) | VAF 9/93 reads (10%) | called by mutect2, pindel
- SYNE1 | c.24643-2del p.X8215_splice (on ENST00000367255 / NM_182961.4; = p.X8144_splice on NM_033071.3) | Splice Site (DEL) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- SZT2 | c.9964del p.Q3322Sfs*8 (on ENST00000634258 / NM_001365999.1; = p.Q3265Sfs*8 on NM_015284.4) | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- TBC1D5 | c.2083del p.A695Pfs*23 | Frame Shift Del (DEL) | VAF 11/125 reads (9%) | called by mutect2, pindel
- TBKBP1 | c.808del p.Q270Rfs*15 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- TCEAL7 | c.233del p.G78Vfs*2 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- TDRD6 | c.541del p.L181Sfs*70 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- TIMM44 | c.560del p.K187Rfs*75 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- TLE4 | c.1047del p.K349Nfs*12 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- TLR3 | c.419del p.N140Ifs*10 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | called by mutect2, pindel
- TMEM198 | c.27del p.F10Sfs*77 | Frame Shift Del (DEL) | VAF 8/87 reads (9%) | called by mutect2, pindel
- TMEM63C | c.811del p.H271Mfs*19 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- TOPBP1 | c.4541del p.N1514Ifs*20 | Frame Shift Del (DEL) | VAF 16/180 reads (9%) | called by mutect2, pindel
- TPCN1 | c.150del p.S51Vfs*19 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- TRAM1 | c.1110del p.E371Rfs*8 | Frame Shift Del (DEL) | VAF 7/77 reads (9%) | called by pindel, varscan2
- TRIM5 | c.812del p.N271Ifs*11 | Frame Shift Del (DEL) | VAF 21/221 reads (10%) | called by mutect2, pindel
- TSPAN9 | c.627del p.M210Cfs*15 | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- TTLL8 | c.2192del p.P731Lfs*6 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- UBAP2 | c.2371+1del p.X791_splice | Splice Site (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- UBE2K | c.399+1del | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- UBE4B | c.3822del p.L1275* (on ENST00000343090 / NM_001105562.3; = p.L1146* on NM_006048.5) | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- UBL4A | c.258del p.R86Sfs*13 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- UBR4 | c.353_359delinsTG p.P118Lfs*22 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by pindel, varscan2*
- UGT1A3 | c.725_726del p.E242Gfs*50 | Frame Shift Del (DEL) | VAF 64/283 reads (23%) | called by pindel, varscan2
- USP34 | c.9605del p.N3202Tfs*20 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel
- VARS1 | c.3426del p.T1143Rfs*? | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- VASN | c.13del p.V5Sfs*103 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- WNK2 | c.4891del p.R1631Afs*42 (on ENST00000297954 / NM_001282394.1; = p.R1594Afs*42 on NM_006648.3) | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- XDH | c.591del p.K197Nfs*21 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- ZC3H10 | c.1001del p.P334Lfs*25 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- ZCCHC8 | c.1323del p.A442Pfs*54 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- ZFHX3 | c.10466del p.F3489Sfs*7 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- ZIC4 | c.102del p.T35Pfs*25 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- ZMIZ1 | c.746del p.G249Afs*66 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- ZNF341 | c.243del p.A82Pfs*44 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- ZNF367 | c.559del p.R187Gfs*47 | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- ZNF493 | c.538del p.T181Lfs*5 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- ZNF536 | c.630del p.D210Efs*4 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ZNF628 | c.2211del p.A738Hfs*45 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ZNF668 | c.76del p.S26Pfs*31 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- ZNF777 | c.2446del p.R816Afs*129 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ZNF778 | c.1341del p.K447Nfs*18 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- ZSWIM4 | c.2022del p.L675Cfs*3 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- ZWILCH | c.60del p.F20Lfs*23 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- CACNB2 | c.198T>C p.N66= (on ENST00000324631 / NM_201596.3; = p.N38= on NM_201571.4) | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV56610684; called by mutect2, varscan2
- GABRG2 | c.1014G>A p.K338= (on ENST00000361925 / NM_001375343.1; = p.K298= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as COSV62715212; called by mutect2, varscan2
- GSK3A | c.1113A>C p.R371= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as COSV55898357; called by mutect2, varscan2
- HELZ2 | c.60C>A p.P20= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV64408917; called by muse, varscan2
- MLLT6 | c.75C>T p.C25= | Silent (SNP) | VAF 25/70 reads (36%) | called by mutect2, varscan2
- NSD3 | c.2958G>C p.L986= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV57671702; called by mutect2, varscan2
- OR2AT4 | c.792C>T p.Y264= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as rs778561210, COSV59406249; called by mutect2, varscan2
- PHLDB1 | c.3936C>T p.Y1312= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs781901332, COSV50619356; called by muse, mutect2, varscan2
- PKP3 | c.513G>A p.G171= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1053787250, COSV58985723; called by muse, mutect2, varscan2
- PLEKHB2 | c.276A>G p.E92= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV52174491; called by muse, varscan2
- PSMD12 | c.399A>G p.E133= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV62065018; called by mutect2, varscan2
- ZNF208 | c.1896T>C p.A632= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV68099595; called by muse, mutect2, varscan2
- AC074085.2 | n.234del | RNA (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ANKRD33 | c.-40del | 5'UTR (DEL) | VAF 5/43 reads (12%) | catalogued as COSV56608264; called by mutect2, pindel
- C3P1 | n.2339C>T | RNA (SNP) | VAF 50/186 reads (27%) | called by mutect2, varscan2
- HMGN2P46 | n.1042del | RNA (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- KIAA0930 | c.853-930del | Intron (DEL) | VAF 4/45 reads (9%) | catalogued as rs764079139; called by pindel, varscan2
- LINC02694 | n.521del | RNA (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- MAGED1 | c.46-342_46-341del | Intron (DEL) | VAF 96/143 reads (67%) | called by mutect2, pindel, varscan2
- PHPT1 | c.286-236del | Intron (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- RPL17 | c.-128del | 5'UTR (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- USH1C | c.1285-7608del | Intron (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
